FM case AD4854 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/ad9775d8-0703-4216-bf34-470a1f87b8e3

Female, 70.2 years: diagnosis not reported by GDC; metastasis biopsied or resected from the bone. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
